Gene-level copy-number profile of tumor specimen REBC-ADJD-TTP1-A from REBC case REBC-ADJD, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ADJD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d66699c9-df46-4df8-a2ed-65b329e75bff.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ADJD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/534111b5-1825-4734-b627-5467b24f3e3b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 129; copy number 2: 58,001; copy number 3: 275.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 129. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
